CCDI case PBBPIV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/746fb1f4-bf2e-4da8-9ed5-0734363640fc

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 15.6 years (5,715 days).

Biospecimens (3 samples)
- Sample 0DE0QP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE0R8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE0TW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
